Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TB-01A (Primary Tumor).

[page 1 of 3]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Pathology Report:

ICD-O-3

Carcinoma, urothelial NOS
CCCF 8/22/13
Site Lateral wall of bladder
C67.2
path
Overlapping lesion of
bladder C67.8
Gr 7/22/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph nodes; lymphadenectomy:

- Twelve lymph nodes, no tumor (0/12).

B. Left pelvic lymph nodes; lymphadenectomy:

- Fourteen lymph nodes, no tumor (0/14).

C. Urinary bladder and prostate; cystoprostatectomy:

- Invasive high grade urothelial carcinoma, infiltrating thru the bladder muscularis propria and focally into the perivesical fat, see pathologic parameters.

- All specimen resection margins, free of tumor.

D. Right distal ureter; excision:

- Portion of ureter, free of tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (microscopic [slide C21]).
4. Tumor distribution: Solitary, 2.7 cm, right posterolateral wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/26).
9. pTNM: pT3a,N0,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

[page 2 of 3]
Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD
Electronically Signed Out by [] MD

Clinical History:

Patient is a year-old male with malignant neoplasm of bladder, part unspecified undergoing cystoprostatectomy, ileo-conduit.

Specimens Received:

- A: Left pelvic lymph nodes
- B: Left pelvic lymph nodes
- C: Bladder and prostate
- D: Right distal ureter, stitch on non margin side

Gross Description:

The specimens are received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin are multiple soft, rubbery, yellow-tan tissue fragments measuring 6.3 x 5.2 x 1.4 cm in aggregate. 17 lymph node candidates are identified and submitted as follows:

- A1: 3 lymph node candidates
- A2: 4 lymph node candidates
- A3: 3 lymph node candidates
- A4: 4 lymph node candidates
- A5: One lymph node candidate, bisected
- A6: One lymph node candidate, bisected
- A7: One lymph node candidate, bisected

B. The second container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin are multiple soft, rubbery, yellow-tan tissue fragments measuring 6.2 x 5.5 by 1.3 cm in aggregate. 13 lymph node candidates are identified and submitted as follows:

- B1: 3 lymph node candidates
- B2: 4 lymph node candidates
- B3: One lymph node candidate, bisected
- B4-B5: One lymph node candidate, bisected, one half in each cassette
- B6: 4 lymph node candidates

C. The third container is additionally identified as, "bladder/prostate". Received fresh and placed in formalin is a 190 g, 14.5 x 9.0 x 5.0 cm cystoprostatectomy specimen consisting of a 6.0 x 6.0 x 2.1 cm bladder with attached mesenteric fat and a 4.4 x 4.0 x 3.9 cm prostate. The right seminal

[page 3 of 3]
vesicles measure 4.1 x 1.3 cm and right vas deferens measures 4.2 x 0.5 cm. The left seminal vesicles measures 3.9 x 1.0 cm and left vas deferens measures 6.5 x 0.4 cm. The right ureteral stump measures 1.5 x 0.4 cm, the left measures 1.2 x 0.4 cm, and each demonstrates an intact, patent lumen.

The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The outer surface of the prostate is smooth. Sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity without evidence of any lesions or indurations.

The opened bladder reveals a 2.7 x 2.5 cm red-tan, friable ulcer (lesion A) located in right posterolateral wall and a 2.5 x 1.0 cm ulcer (lesion B) in the inferoposterior wall/prostatic urethra. In addition, a pink edematous mucosa is noted on the left lateral wall measuring 2.0 x 1.5 cm. On cut section, lesion B extends into but not through the mucosa and is 2.0 cm from the deep margin. On cut section, the lesion A extends into but not through the mucosa and is 1.7 - 2.1 cm from the deep margin. The surrounding bladder mucosa is smooth, wrinkled, pink-tan with a uniform 1.1 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

- C1: Distal prostatic urethral margin
- C2: Right ureter resection margin
- C3: Left ureter resection margin
- C4: Prostate apex
- C5-C7: Representative right lobe of prostate
- C8-C10: Representative left lobe of prostate
- C11-C16: All sections of ulcer/lesion in the inferoposterior wall/prostatic urethra (Lesion B)
- C17-C20: All sections of the edematous mucosa in the left lateral wall
- C21-C28: All sections of the ulcer in the right posterior lateral wall (Lesion A)
- C29: Representative section of uninvolved bladder mucosa, posterior wall
- C30: Representative section of uninvolved mucosa, bladder dome
- C31-C32: Representative section of uninvolved bladder mucosa, anterior wall

D. The fourth container is additionally identified as, "right distal ureter, stitch on non-margins side".

Received fresh and placed in formalin is a 1.1 x 0.9 cm, soft, pink-tan tubular specimen grossly resembling ureter which is oriented by a long stitch on the non-margins side. The margins side is sectioned and submitted en face as D1 and the remaining specimen is bisected and submitted in toto as D2.

Diagn. Discrepancy		✓
SPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 07e09c2a-6a59-4eda-9172-df0182e78a51 (TCGA-FD-A6TB.D324203B-97F7-4EDF-B1D2-217F63ACAF92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).